Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9UB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9UB-01A (Primary Tumor).

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Biopsy of uterine cervix:

- Poorly differentiated invasive squamous cell carcinoma.
- Angiolymphatic and perineural invasions not observed.

ICD-O-3
Carcinoma, squamous
cell NOS 8070/3
Site: Cervix NOS C539
J23/7/14

Source: NCI Genomic Data Commons file bdf71a1b-adff-49d7-9057-3e77018ce8b1 (TCGA-VS-A9UB.73D61A64-9435-4E72-898C-3A4E7C109CF3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).